Somatic mutation profile of tumor specimen TARGET-20-PARZWH-09A (aliquot TARGET-20-PARZWH-09A-02D) from TARGET case TARGET-20-PARZWH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.6 years (4,243 days).
Specimen TARGET-20-PARZWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b871dce-0d44-4993-a177-9e254defb9f1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZWH-14A (Bone Marrow Normal), aliquot TARGET-20-PARZWH-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeaeb651-c689-4372-80c4-032e0e561064

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.949_950insGTC p.E316_L317insR | In Frame Ins (INS) | VAF 33/87 reads (38%) | catalogued as COSV57198131, COSV57200918; called by mutect2, pindel, varscan2
- PALB2 | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
